Surgical pathology report (de-identified scan), TCGA case TCGA-ZC-AAA7, project TCGA-THYM (Thymoma), tissue source site  University of Mannheim, specimen TCGA-ZC-AAA7-01A (Primary Tumor).

Original report (translation):

Microscopy / Assesment:

Histologically, we recognize a polycyclic limited, indicated lobular structured tumour, which infiltrates vessels in several places. Multifocal tumour necrosis occur. The tumour cells shows a syncytial growth pattern with no discernible cell borders and clear pleomorphic nuclei with prominent nucleoli. In the background, sparse lymphocytes. Immunohistochemistry shows a strong expression of CK19, EMA , as well as of CD5 and CD117 . Immature T cells (TDT) do not occur. In summary, there is a rather rare variant of a thymic carcinoma, specifically a so-called undifferentiated thymic carcinoma with morphological aspects of a lymphoepithelial-like carcinoma.

Follow-up report:

I report on the outcome of the EBER hybridization. In this case there is no positive response. In summary, it is formally an undifferentiated thymic carcinoma.

Short report:

Date of tumour procurement:

Anatomic site of tumor procured:
Thymus

Final diagnosis:
Undifferentiated thymic carcinoma

Discrepancy between histology on frozen section and paraffin section:
None

ICD-O-3
Thymoma, type C 8586/3
Site: Thymus C37.9
PA 3/12/14

Source: NCI Genomic Data Commons file 532ac8ae-07ab-47b3-8d5f-cd1078c7b171 (TCGA-ZC-AAA7.68641E71-3055-4C32-957E-F482B3BF4700.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).